Gene-level copy-number profile of tumor specimen C3N-02035-02 from CPTAC case C3N-02035, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 64.5 years (23,576 days).
Specimen C3N-02035-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a800d983-e895-4176-bff5-0725c9428f55.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02035-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,857 have no estimate.
https://portal.gdc.cancer.gov/files/3d23d6df-0b3a-4936-93a1-a2173c8a0da7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 382; copy number 1: 13; copy number 2: 20,382; copy number 3: 23,524; copy number 4: 11,441; copy number 5: 1,470; copy number 6: 851; copy number 7: 351; copy number 8: 39; copy number 9: 19; copy number 10: 14; copy number 11: 7; copy number 12: 90; copy number 13: 32; copy number 14: 67; copy number 15: 13; copy number 16: 20; copy number 17: 43; copy number 18: 1; copy number 20: 6; copy number 26: 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:180,573,464–180,574,027, 1 gene: NDUFB5P1.
- chr4:181,874,438–182,145,249, 2 genes (within-gene range 0–2): TENM3-AS1, CCNHP1.
- chr4:182,144,852–182,190,382, 2 genes (within-gene range 0–2): AC108142.1, MIR1305.
- chr7:37,032–525,238, 15 genes: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92.
- chr7:561,958–565,619, 1 gene (within-gene range 0–5): PRKAR1B-AS2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr17:16,786,489–16,832,830, 9 genes (within-gene range 0–2): USP32P1, SRP68P1, AC098850.4, AC098850.1, FAM106C, AC022596.1, NOS2P4, KRT16P6, KRT16P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 703 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:40,457,292–41,962,130, 22 genes, copy number 13: RPL14, ZNF619, ZNF620, RNU5B-2P, ZNF621, RPL5P10, EEF1GP3, AC122683.1, HMGN2P24, AC099560.1, AC099560.2, AC099541.1, AC009743.1, MRPS31P1, CTNNB1, ULK4, AC099537.1, RN7SKP58, ATP6V0E1P2, Y_RNA, U8, RPL36P20.
- chr3:45,676,369–46,266,706, 17 genes, copy number 14–16 (within-gene range 3–16): LIMD1-AS1, SACM1L, RN7SL145P, AC098476.1, SLC6A20, LZTFL1, AC099782.1, SDHDP4, CCR9, Y_RNA, FYCO1, CXCR6, XCR1, NRBF2P2, FLT1P1, CCR3, CCR1.
- chr3:56,557,161–78,115,457, 251 genes, copy number 7–20 (broad region; genes not listed).
- chr3:79,957,566–82,808,021, 20 genes, copy number 7–26: HMGB1P38, OSBPL9P1, HNRNPA3P8, AC108740.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1, AC107302.2, AC107302.1, GBE1, RNU2-28P, SETP6, AC017015.1, AC017015.2, AC129807.1, LINC02008, RPL7AP23, CYP51A1P1.
- chr3:86,362,132–86,991,149, 4 genes, copy number 13–16: RN7SKP284, LINC02070, AC108706.1, VGLL3.
- chr3:94,047,836–94,507,620, 4 genes, copy number 7 (within-gene range 4–7): DHFR2, NSUN3, RBBP4P2, ARMC10P1.
- chr3:97,822,011–98,053,739, 5 genes, copy number 8: CRYBG3, AC110491.2, RIOX2, GABRR3, OR5BM1P.
- chr3:108,907,792–112,585,579, 57 genes, copy number 7–17: GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2, AC092916.2, ZBED2, NT5C3AP2, PLCXD2, PLCXD2-AS1, PHLDB2, AC117509.1, ABHD10, TAGLN3, RFKP2, TMPRSS7, C3orf52, MIR567, GCSAM, TBILA, SLC9C1, AC128688.1, AC112487.1, AC112487.2, CD200, AC092894.1, BTLA, OR7E100P, AC092692.1, ATG3, SLC35A5.
- chr3:194,276,682–197,029,817, 110 genes, copy number 12–14 (broad region; genes not listed).
- chr7:5,072,125–5,563,902, 18 genes, copy number 8–10 (within-gene range 5–10): RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, ACTB, AC006483.2, AC006483.1.
- chr9:12,134–7,598,377, 134 genes, copy number 7 (broad region; genes not listed).
- chr9:63,974,762–66,179,474, 47 genes, copy number 7: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr14:18,333,726–18,419,273, 4 genes, copy number 11: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr21:10,521,553–13,120,807, 10 genes, copy number 8–9 (within-gene range 4–9): TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 13. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
